Somatic mutation profile of tumor specimen TCGA-HT-8563-01A (aliquot TCGA-HT-8563-01A-11D-2395-08) from TCGA case TCGA-HT-8563, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 31.0 years (11,305 days).
Specimen TCGA-HT-8563-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 99f77101-a39f-4c98-85c7-2239cf6152c2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-8563-10A (Blood Derived Normal), aliquot TCGA-HT-8563-10A-01D-2396-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ae1ff65b-b44c-4155-8be5-601dbcfa112b

The open-access MAF lists 32 somatic variants for this specimen: 20 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 10, Nonsense Mutation 2, RNA 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 23/102 reads (23%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 14/89 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.455C>A p.P152Q | Missense Mutation (SNP) | VAF 20/84 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CD147772, CM941327, COSV52666949, COSV52773466, COSV53038279; called by muse, mutect2, varscan2
- ATRX | c.4700-1G>C p.X1567_splice | Splice Site (SNP) | VAF 37/169 reads (22%) | catalogued as COSV64877980, COSV64878764; called by muse, mutect2, varscan2
- CEP128 | c.2704C>G p.L902V | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as COSV55379552; called by muse, mutect2, varscan2
- GPRASP2 | c.1112A>G p.D371G | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV59991579; called by muse, mutect2, varscan2
- ITIH6 | c.2333G>A p.C778Y | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV54490054; called by muse, mutect2, varscan2
- KDM2B | c.368T>G p.F123C | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65641862; called by muse, mutect2, varscan2
- KSR2 | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 89/199 reads (45%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.885); catalogued as rs1386110457, COSV60380733; called by muse, mutect2, varscan2
- LRIT1 | c.599A>G p.D200G | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV64513625; called by muse, mutect2
- MGAT5 | c.1746C>G p.N582K | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as COSV56097410; called by muse, mutect2, varscan2
- MYO7A | c.1788T>A p.D596E | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (1); PolyPhen probably damaging (0.99); catalogued as COSV68685059; called by muse, mutect2, varscan2
- OLFML2B | c.1156G>A p.A386T | Missense Mutation (SNP) | VAF 53/225 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.028); catalogued as rs776825210, COSV54197076; called by muse, mutect2, varscan2
- POLR2C | c.722C>G p.P241R | Missense Mutation (SNP) | VAF 7/130 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99538299; called by muse, mutect2
- SLC44A5 | c.1139T>C p.L380S | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63766971; called by muse, mutect2, varscan2
- SOS2 | c.684T>G p.F228L | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.036); catalogued as COSV53568885; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.712A>T p.I238L | Missense Mutation (SNP) | VAF 37/197 reads (19%) | PolyPhen benign (0.42); catalogued as COSV60335536; called by muse, mutect2, varscan2
- STK32B | c.846C>G p.Y282* | Nonsense Mutation (SNP) | VAF 12/142 reads (8%) | catalogued as COSV51492153; called by muse, mutect2
- TSC2 | c.2352A>C p.K784N | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.27); catalogued as COSV54767222; called by mutect2, varscan2
- ZBTB20 | c.709C>T p.Q237* (on ENST00000474710 / NM_001164342.2; = p.Q164* on NM_015642.6 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 34/125 reads (27%) | catalogued as COSV61853317; called by muse, mutect2, varscan2
- ACSM2A | c.1428G>A p.S476= (on ENST00000219054; = p.S397= on NM_001308169.2) | Silent (SNP) | VAF 23/119 reads (19%) | catalogued as rs773909818, COSV54585683; called by muse, mutect2, varscan2
- ANAPC5 | c.69G>C p.V23= | Silent (SNP) | VAF 19/108 reads (18%) | catalogued as COSV55843075; called by muse, mutect2, varscan2
- CFAP46 | c.483C>T p.N161= | Silent (SNP) | VAF 33/108 reads (31%) | catalogued as rs181449154; called by muse, mutect2, varscan2
- DERL3 | c.516C>T p.D172= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs772551294, COSV51955065; called by muse, mutect2, varscan2
- LRRIQ1 | c.4002A>G p.E1334= | Silent (SNP) | VAF 51/146 reads (35%) | catalogued as COSV67832167; called by muse, mutect2, varscan2
- MAGEC1 | c.1872T>C p.S624= | Silent (SNP) | VAF 151/575 reads (26%) | catalogued as COSV53574298; called by muse, mutect2, varscan2
- MPP7 | c.462G>A p.K154= | Silent (SNP) | VAF 9/141 reads (6%) | catalogued as COSV61733638; called by muse, mutect2
- OR5AN1 | c.132C>T p.L44= | Silent (SNP) | VAF 53/250 reads (21%) | catalogued as COSV58322280; called by muse, mutect2, varscan2
- PPARGC1A | c.1476A>G p.E492= | Silent (SNP) | VAF 30/147 reads (20%) | catalogued as COSV53528533; called by muse, mutect2, varscan2
- RIPOR1 | c.2862G>A p.P954= (on ENST00000379312 / NM_001193522.2; = p.P950= on NM_024519.4) | Silent (SNP) | VAF 33/135 reads (24%) | catalogued as rs146173403; called by muse, mutect2, varscan2
- CHM | c.1245-2472C>G | Intron (SNP) | VAF 38/139 reads (27%) | catalogued as COSV100753226; called by muse, mutect2, varscan2
- SERPINA13P | n.212C>G | RNA (SNP) | VAF 2/14 reads (14%) | called by muse, mutect2
